Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5436, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5436-01A (Primary Tumor).

[page 1 of 2]
History Case Pathology Report

** Case imported from legacy computer system. The format of this report does not match the original case. **
* the section "SPECIMEN" may have been added. **

DIAGNOSIS

- (A) FLOOR OF MOUTH CANCER, EXCISION:
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED WITH
KERATINIZATION.
- (B) RIGHT NECK DISSECTION, LEVEL I, EXCISION:
Four lymph nodes, no tumor present.
Salivary gland unremarkable.
- (C) RIGHT NECK DISSECTION, LEVEL II, EXCISION:
METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF THREE LYMPH NODES,
(1/3).
No extracapsular extension is identified.
- (D) RIGHT NECK DISSECTION, LEVEL III, EXCISION:
Two lymph nodes, no tumor present.
- (E) LEFT LINGUAL NERVE, EXCISION:
Nerve and salivary gland tissue, no tumor present.
- (F) LYMPH NODE, MENTAL TRIANGLE, EXCISION:
METASTATIC KERATINIZING SQUAMOUS CELL CARCINOMA IN ONE OF ONE
LYMPH NODE (1/1).
No extra-capsular extension identified.
- (G) FLOOR OF MOUTH, TONGUE, ANTERIOR MANDIBLE, AND LEFT NECK DISSECTION,
EXCISION:
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATE TO POORLY
DIFFERENTIATED.
PERINEURAL INVASION, EXTENSIVE.
MAXIMUM DEPTH OF INVASION, 1.7 CM.
Resection margins free of tumor.
METASTATIC SQUAMOUS CELL CARCINOMA IN FIVE OF FORTY-ONE LYMPH NODES
5/41.
EXTRA-CAPSULAR EXTENSION IDENTIFIED.
Chronic sialadenitis.
- (H) TEETH:
(Gross Identification Only)

GROSS DESCRIPTION

- (A) FLOOR OF MOUTH CANCER - A tan-pink soft tissue fragment (0.9 x 0.8 x 0.2 cm). The entire specimen is submitted for frozen section in cassette A.
SQUAMOUS CARCINOMA, INVASIVE.
- (B) RIGHT NECK DISSECTION, LEVEL 1 - A portion of adipose tissue and a

[page 2 of 2]
History Case Pathology Report

portion of salivary gland, 7.0 x 3.0 x 2.5 cm in toto. The portion of salivary gland is 4.0 x 2.5 x 2.5 cm and is grossly unremarkable. Multiple lymph nodes up to 1.2 cm in diameter are identified.

SECTION CODE: B1, salivary gland; B2, one lymph node cut into three pieces; B3, one lymph node bisected; B4, one lymph node; B5, adipose tissue with possible lymph node.

(C) RIGHT NECK DISSECTION, LEVEL 2 - A piece of adipose tissue containing multiple lymph nodes. The specimen is 2.5 x 1.5 x 1.5 cm. The largest lymph node is 1.5 x 0.4 x 0.4 cm.

SECTION CODE: C1, one lymph node bisected; C2 and C3, one lymph node; C4 and C5, adipose tissue containing possible lymph node.

(D) RIGHT NECK DISSECTION, LEVEL 3 - A piece of fibroadipose tissue (2.5 x 1.4 x 1.2 cm) and contains multiple lymph nodes up to 0.8 cm in greatest dimension.

SECTION CODE: D1 and D2, one lymph node bisected in each cassette; D3 and D4, adipose tissue containing possible lymph nodes.

(E) LEFT LINGUAL NERVE - Two tan-pink soft tissue fragments (0.3 x 0.2 x 0.1 cm in aggregate). The entire specimen is submitted for frozen section in cassette E1.

*FS/DX: NERVE, NO TUMOR PRESENT.

(F) MENTAL TRIANGLE NODE - One lymph node 0.8 x 0.4 x 0.4 cm. Specimen is bisected and entirely submitted in F.

(G) FLOOR OF MOUTH, TONGUE, ANTERIOR MANDIBLE, AND LEFT NECK DISSECTION - A portion of tongue with attached mandible and neck dissection with overall measurements of 5.5 x 6.5 x 2.5 cm. An ulcerated fungating and light tan mass is identified involving the base of the tongue measuring 5.0 x 4.0 x 1.0 cm. The lesion is surrounded by mucosa and no involvement of the surgical margin of resection is seen. Deep margin is at least 0.2 mm from the tumor. The specimen is submitted sequentially from anterior to posterior in G2-G22.

SECTION CODE: Level 1 - G23, salivary gland; G24-G25, one lymph node with metastatic carcinoma; G26-G31, one lymph node bisected in each cassette. Level 2 lymph node - G32-G33, one lymph node; G34-G35, each contains one lymph node bisected; G36-G38, each contains three lymph nodes. Level 4 lymph nodes - G39 and G40, one lymph node bisected in each cassette; G41, three lymph nodes; G42-G44, adipose tissue containing possible lymph nodes.

*FS/DX: LATERAL AND DEEP MARGIN, FREE OF TUMOR.

(H) TEETH - Seven teeth measuring up to 2.1 x 1.1 x 1.1 cm. Submitted for gross ID only.

Source: NCI Genomic Data Commons file 8cf1b982-2376-4441-9d9b-79592ce27b8b (TCGA-CV-5436.5586BD53-C400-4F42-B4B2-914538FF0FEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).